Gene-level copy-number profile of tumor specimen TCGA-77-7337-01A from TCGA case TCGA-77-7337, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 65.9 years (24,065 days).
Specimen TCGA-77-7337-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.eb018274-5208-41f6-b3d1-51adc648b914.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-77-7337-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d4f1671b-c8cb-46ef-ac71-351352edd937

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 20,681; copy number 2: 30,454; copy number 3: 6,817; copy number 4: 1,201; copy number 5: 113; copy number 6: 440; copy number 7: 92; copy number 11: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-77-7337-01A-21D-2041-01): tumor purity 0.52, ploidy 1.89, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:90,370,123–90,683,123, 2 genes: RN7SKP248, AC093729.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 657 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:194,344,190–198,772,356, 57 genes, copy number 5–6 (within-gene range 4–6): LINC01821, AC106883.1, AC073973.1, Metazoa_SRP, AC006196.1, LINC01790, AC010983.1, AC104823.1, AC064834.1, RNU6-169P, LINC01825, LINC01827, SLC39A10, AHCYP5, RNU6-915P, DNAH7, E2F3P2, AC114760.1, STK17B, AC114760.2, HECW2, HECW2-AS1, RN7SL820P, AC068544.2, CCDC150, AC068544.1, GTF3C3, C2orf66, AC012486.1, PGAP1, ANKRD44, HNRNPA3P15, RPL4P7, ANKRD44-AS1, ANKRD44-IT1, ATP5MC2P3, AC010746.2, NPM1P46, SF3B1, AC010746.1, RNU6-1029P, COQ10B, HSPD1, HSPE1, HSPE1-MOB4, MOB4, AC020550.1, RFTN2, AC020550.2, AC011997.1, MARS2, BOLL, PLCL1, AC011997.2, AC020719.1, LINC01923, AC019330.1.
- chr5:16,473,038–21,032,845, 74 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr5:23,013,048–45,895,970, 335 genes, copy number 5–7 (broad region; genes not listed).
- chr8:35,235,475–35,796,550, 1 gene, copy number 11 (within-gene range 1–11): UNC5D.
- chr8:35,525,176–43,674,591, 190 genes, copy number 6–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 18,297. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
